Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0T5, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0T5-01A (Primary Tumor).

[page 1 of 3]
Specimen:

Received:

Status:

Spec Type: SURGICAL P

Subm Dr:

BREAST CANCER

100-0-3
Carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9 hr 1/27/94

DATE:

DOCTOR(S):

- A. LEFT BREAST SUPERFICIAL MARGIN RE-EXCISION
- B. RIGHT BREAST
- C. LEFT BREAST

PART A RECEIVED LABELED [REDACTED] LEFT BREAST UPPER OUTER QUADRANT SUPERFICIAL MARGIN REEXCISION STITCH NEW MARGIN, IS AN IRREGULAR PORTION OF YELLOW-PINK FATTY TISSUE MEASURING 12.5 X 7.5 X 1.0 CM IN GREATEST DIMENSIONS. A SUTURE DENOTES THE NEW MARGIN. THIS SIDE IS MARKED WITH BLUE INK WITH A PERIMETER OF BLACK INK. REPRESENTATIVE SECTIONS TO INCLUDE APPROXIMATELY 40% OF THE SPECIMEN ARE SUBMITTED LABELED A1 THROUGH 10.

PART B RECEIVED LABELED [REDACTED] RIGHT BREAST STITCH AT 12 O'CLOCK, IS A SIMPLE MASTECTOMY SPECIMEN MEASURING 24 X 18.5 X 5.5 CM. THE NIPPLE IS GROSSLY UNREMARKABLE WITHIN A 7 X 3.5-CM SKIN ELLIPSE. A SUTURE DENOTES 12 O'CLOCK. THE SUPERFICIAL ASPECT IS MARKED WITH BLUE INK, THE DEEP WITH BLACK. SECTIONING REVEALS DENSE GRAY-TAN FIBROUS TISSUE INTERMIXED WITH YELLOW FATTY TISSUE. THE FIBROUS TISSUE IS PRIMARILY IN THE MID TO LOWER OUTER QUADRANT AREAS. THIS IS SURROUNDED BY BLAND YELLOW FATTY TISSUE. THE FIBROUS TISSUE COMPRISES UP TO 40% OF THE SPECIMEN. SECTIONS ARE SUBMITTED AS FOLLOWS: B1--NIPPLE, B2--CENTRAL DEEP MARGIN, B3 AND 4--UPPER INNER QUADRANT, B5 AND 6--UPPER OUTER QUADRANT, B7 AND 8--LOWER OUTER QUADRANT, B9 AND 10--LOWER INNER QUADRANT.

PART C RECEIVED FRESH LABELED [REDACTED] LEFT BREAST STITCH AT 12 O'CLOCK, IS A 26 X 18 X 6-CM SIMPLE MASTECTOMY SPECIMEN. THE NIPPLE IS UNREMARKABLE WITHIN AN 8 X 4.2-CM SKIN ELLIPSE. A SUTURE DENOTES 12 O'CLOCK. THE SUPERFICIAL ASPECT IS MARKED WITH BLUE INK, THE DEEP WITH BLACK. SECTIONING REVEALS A PINK-TAN FIRM GRITTY MASS AT 3 O'CLOCK LATERAL BREAST. THIS AREA MEASURES 4.5 X 2.4 X 4.0 CM IN GREATEST DIMENSIONS. THE TISSUE BETWEEN THIS LESION AND THE DEEP MARGIN CONSISTS OF YELLOW FATTY TISSUE AND PINK-TAN FIBROUS TISSUE. THE MARGIN GROSSLY IS 0.8 CM AWAY. THIS IS 0.8 CM FROM THE PROXIMAL MARGIN. THERE IS A SECOND PALPABLE AREA OF FIRMNESS IN THE UPPER OUTER QUADRANT AT THE LATERAL EDGE OF THE SPECIMEN WHICH WHEN SECTIONED REVEALS NO GROSS LESION. BY PALPATION, THIS AREA IS 2 CM IN GREATEST DIMENSION. THIS AREA DOES DEMONSTRATE YELLOW-WHITE COLORATION SUGGESTIVE OF GROSS FAT

9cm
7.5cm
2nd 40Q

[page 2 of 3]
Patient: [REDACTED]

(Continued)

Specimen

Received:

Status: [REDACTED]

Spec Type: SURGICAL P

Subm Dr: [REDACTED]

(Continued)

NECROSIS. THIS AREA IS 5 CM FROM THE LESION. CENTRALLY, THE BREAST DOES DEMONSTRATE GRAY-TAN FIBROUS TISSUE. THE PERIMETER OF THE SPECIMEN IS BLAND YELLOW FATTY TISSUE. THE FIBROUS TISSUE COMPRISES NO MORE THAN 25% OF THE SPECIMEN. SECTIONS ARE SUBMITTED AS FOLLOWS: C1--NIPPLE AND SKIN (MIRROR IMAGE TO PROTOCOL), C2 AND 3--FULL CROSS-SECTION OF LESION (MIRROR IMAGE TO TISSUE TAKEN PER PROTOCOL), C4--LESION AND DEEP MARGIN, C5 AND 6--LESION AND SUPERFICIAL MARGIN, C7 AND 8--FULL CROSS-SECTION OF LESION (MIRROR IMAGE TO TISSUE TAKEN PER PROTOCOL), C9 AND 10--TISSUE EXTREME UPPER OUTER QUADRANT WITH INDURATION, C11--CENTRAL BREAST TISSUE WITH FIBROSIS, C12--UPPER OUTER QUADRANT, C13--UPPER INNER QUADRANT, C14--LOWER INNER QUADRANT, C15--LOWER OUTER QUADRANT.

PROCEDURES:

88307/3, A BLK/10, B BLK/10, C BLK/15

PART A LEFT BREAST UPPER OUTER QUADRANT SUPERFICIAL MARGIN REEXCISION: FIBROADIPOSE TISSUE WITH NO EVIDENCE OF NEOPLASM. THE NEW INKED MARGIN IS FREE OF NEOPLASM. FOCUS OF PREVIOUS BIOPSY SITE CHANGE WITH ORGANIZING FAT NECROSIS WITH REACTIVE FIBROSIS.

PART B RIGHT BREAST, SIMPLE MASTECTOMY: FIBROCYSTIC DISEASE WITH PATCHY FIBROSIS, APOCRINE METAPLASIA, CYST FORMATION AND A SMALL FIBROADENOMA. NO EVIDENCE OF ATYPIA OR MALIGNANCY. UNREMARKABLE NIPPLE SKIN.

PART C LEFT BREAST, SIMPLE MASTECTOMY:

1. MODERATELY DIFFERENTIATED INTRADUCTAL AND INFILTRATING DUCT CARCINOMA, NUCLEAR GRADE II WITH LOW MITOTIC INDEX, WITH AN IN SITU COMPONENT OF APPROXIMATELY 10% OF SOLID AND CRIBRIFORM TYPE WITH FOCI OF INTRADUCTAL NECROSIS.
2. THE TUMOR GROSSLY MEASURES 4.5 CM IN GREATEST DIMENSION. THE NIPPLE, DEEP AND SUPERFICIAL MARGINS ARE FREE OF NEOPLASM.
3. FOCI SUSPICIOUS FOR LYMPHATIC INVASION ARE PRESENT.
4. BIOPSY SITE CHANGE WITH REACTIVE FIBROSIS AND ORGANIZING FAT NECROSIS INCLUDING AN AREA FROM THE UPPER OUTER QUADRANT WHICH MAY REPRESENT A PREVIOUS SENTINEL NODE BIOPSY SITE.
5. FIBROCYSTIC CHANGE WITH PATCHY DENSE FIBROSIS AND CYST FORMATION.

② FCC
AM
cyst FA

① DCIS 10%
solid/criform
rec
IDC 2/2/1
4.5cm
skin/nipple

+LVI

FCC
cyst

[page 3 of 3]
Patient:

(Continued)

Specimen:

Received:

Status:

Spec Type: SURGICAL P

Subm Dr:

1

Signed

(prelim.)

(signature on file)

Source: NCI Genomic Data Commons file 75a4d2da-6b7d-426c-93c5-7791eb730699 (TCGA-A2-A0T5.7B1E6EEB-3B61-4CE8-B695-ED11C2EF169F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).